Somatic mutation profile of tumor specimen 0DH72Z from CCDI case PBBUDY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sertoli cell tumor, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 14.3 years (5,205 days).
Specimen 0DH72Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0ac8e55-ea96-41b8-b1ba-d27a348dba4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH6ZW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/011667ec-68e8-4ab8-805c-4133039a2ac3

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 444/482 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- DNAH3 | c.1836G>T p.K612N | Missense Mutation (SNP) | VAF 408/904 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- HSD11B1L | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 302/596 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- MAP2 | c.2743A>T p.I915F | Missense Mutation (SNP) | VAF 551/1052 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- PPP4R1 | c.2456C>G p.T819R (on ENST00000400556 / NM_001042388.3; = p.T802R on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 287/681 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SLTM | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 155/333 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF569 | c.862C>G p.H288D | Missense Mutation (SNP) | VAF 149/330 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPC3 | c.1033-4244A>T | Intron (SNP) | VAF 306/766 reads (40%) | called by muse, mutect2, varscan2
- LMO3 | c.-9+22G>C | Intron (SNP) | VAF 140/450 reads (31%) | called by muse, mutect2, varscan2
- OPCML | c.-14T>G | 5'UTR (SNP) | VAF 125/264 reads (47%) | called by mutect2, varscan2
- QTRT1 | c.862-32A>G | Intron (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- TTC3 | c.845+86G>C | Intron (SNP) | VAF 24/583 reads (4%) | called by muse, mutect2
